Gene-level copy-number profile of tumor specimen TCGA-61-2102-01A from TCGA case TCGA-61-2102, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.6 years (27,256 days).
Specimen TCGA-61-2102-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7d0cc9f7-b9ad-4338-a6ea-2d815502dbfe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2102-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/adb50dd0-0d51-41f6-abfa-379d75a11d46

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 2: 7,848; copy number 3: 792; copy number 4: 20,234; copy number 5: 5,469; copy number 6: 17,232; copy number 7: 1,234; copy number 8: 2,924; copy number 9: 1,717; copy number 10: 1,626; copy number 11: 16; copy number 12: 301; copy number 13: 162; copy number 15: 9; copy number 17: 9; copy number 27: 7; copy number 28: 32; copy number 29: 29; copy number 30: 8; copy number 31: 15; copy number 33: 94; copy number 35: 2; copy number 40: 11; copy number 44: 24; copy number 51: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2102-01A-01D-0663-01): tumor purity 0.92, ploidy 2.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:86,764,298–86,771,041, 1 gene: AC130467.1.
- chr17:31,272,013–31,346,190, 5 genes: OMG, EVI2B, AC134669.1, EVI2A, AK4P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,053 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–152,047,907, 353 genes, copy number 9 (broad region; genes not listed).
- chr1:155,913,045–156,625,725, 42 genes, copy number 10: KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1, MEF2D, Y_RNA, AL365181.1, IQGAP3, TTC24, NAXE, GPATCH4, AL365181.4, HAPLN2.
- chr1:163,111,121–164,980,137, 23 genes, copy number 9 (within-gene range 8–9): RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P.
- chr2:154,590,407–242,160,153, 1,504 genes, copy number 9–12 (broad region; genes not listed).
- chr3:161,816,909–169,038,416, 58 genes, copy number 9: AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr3:173,396,284–174,378,005, 6 genes, copy number 9 (within-gene range 8–9): NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1.
- chr3:174,631,823–174,632,064, 1 gene, copy number 9: RN7SKP40.
- chr5:142,592,178–142,761,035, 4 genes, copy number 9 (within-gene range 4–9): FGF1, AC005592.1, LINC01844, AC005592.2.
- chr5:142,859,604–142,868,922, 1 gene, copy number 9: ARHGAP26-AS1.
- chr6:36,948,263–37,699,306, 21 genes, copy number 11–17: PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1.
- chr6:41,026,895–41,406,561, 23 genes, copy number 10: UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2.
- chr6:55,106,460–63,779,336, 69 genes, copy number 13 (within-gene range 8–13) (broad region; genes not listed).
- chr6:66,710,242–70,561,174, 31 genes, copy number 15–31 (within-gene range 8–31): AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P.
- chr6:70,856,679–71,127,105, 4 genes, copy number 17 (within-gene range 8–17): B3GAT2, AL096709.1, BECN1P2, U3.
- chr7:14,814,131–57,837,046, 823 genes, copy number 9–10 (broad region; genes not listed).
- chr7:109,322,320–110,592,204, 9 genes, copy number 9: AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, AC073326.2.
- chr7:110,724,159–110,725,825, 1 gene, copy number 9: AC073326.1.
- chr9:115,252,538–118,764,345, 30 genes, copy number 9: AL355601.1, AL691420.1, U2, LINC00474, AL691426.1, PAPPA, PAPPA-AS2, AL137024.1, PAPPA-AS1, ASTN2, ASTN2-AS1, AL133284.1, TRIM32, AL157829.1, RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1, TPT1P9, AL355592.1, LINC02578, TUBB4BP6.
- chr10:74,506,081–76,560,994, 40 genes, copy number 9: AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1.
- chr12:15,620,134–15,882,329, 1 gene, copy number 40 (within-gene range 6–40): EPS8.
- chr12:15,780,068–19,108,183, 37 genes, copy number 29–40: AC073651.1, AC073651.2, STRAP, DERA, EGLN3P1, SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1, SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1.
- chr12:19,147,074–19,176,589, 2 genes, copy number 29: AC092828.1, RN7SL459P.
- chr12:19,404,045–27,972,733, 150 genes, copy number 28–51 (broad region; genes not listed).
- chr12:28,164,958–28,165,662, 1 gene, copy number 33: AC022364.2.
- chr12:31,729,117–31,993,107, 13 genes, copy number 9 (within-gene range 4–9): AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1.
- chr13:89,361,160–94,408,020, 48 genes, copy number 9 (within-gene range 8–9): SP3P, LINC02336, LINC01040, LINC00353, RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.2, AL354811.1, GPC6, AL160159.1, HNRNPA1P29, GPC6-AS2, RNA5SP35, GPC6-AS1.
- chr13:104,125,930–107,867,496, 32 genes, copy number 9 (within-gene range 8–9): AL136524.1, RPL7P45, AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL163534.1, AL162574.2, PPIAP24, AL162574.1, AL162574.3, AL354741.1, FAM155A, SNORD31B, AL445649.1, MIR1267.
- chr16:46,469,341–46,831,180, 15 genes, copy number 9 (within-gene range 3–9): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87.
- chr16:73,386,771–73,504,954, 1 gene, copy number 12 (within-gene range 2–12): LINC01568.
- chr16:77,741,468–78,066,761, 9 genes, copy number 13: AC092134.1, AC092134.3, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr16:78,123,243–78,526,535, 7 genes, copy number 13: AC079414.3, AC009044.1, WWOX-AS1, AC106743.1, LSM3P5, AC046158.1, AC046158.4.
- chr16:80,040,662–80,804,598, 9 genes, copy number 12 (within-gene range 2–12): AC092130.1, AC022166.1, AC105411.1, AC022166.2, DYNLRB2, AC108097.1, LINC01227, CDYL2, AC099313.1.
- chr16:81,445,170–81,711,762, 1 gene, copy number 10 (within-gene range 2–10): CMIP.
- chr16:81,611,348–82,175,803, 14 genes, copy number 10: MIR6504, AC092135.2, AC092135.1, AC092135.3, AC099524.1, PLCG2, RN7SKP176, AC092142.2, SDR42E1, HSD17B2, AC092142.1, MTCYBP28, MPHOSPH6, AC138304.1.
- chr17:26,981,694–28,897,733, 119 genes, copy number 12 (broad region; genes not listed).
- chr19:4,838,341–6,020,363, 36 genes, copy number 9: PLIN3, ARRDC5, UHRF1, MIR4747, KDM4B, PTPRS, AC022517.1, RPL32P34, AC005790.1, ZNRF4, TINCR, SNRPEP4, SAFB2, SAFB, RPL36, MICOS13, HSD11B1L, LONP1, CATSPERD, PRR22, AC011499.1, DUS3L, NRTN, FUT6, FUT3, AC024592.2, FUT5, AC024592.3, NDUFA11, AC024592.1, AC104532.1, VMAC, AC104532.2, CAPS, RANBP3, AC011444.1.
- chr19:8,308,768–17,342,731, 515 genes, copy number 10–13 (within-gene range 2–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
